Gene-level copy-number profile of tumor specimen TCGA-32-1970-01A from TCGA case TCGA-32-1970, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,613 days).
Specimen TCGA-32-1970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.835361d0-0117-4bd9-8f4f-c25957b7993a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-32-1970-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a86e9576-402a-46fe-b1d3-65257abf5058

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,128; copy number 3: 3,613; copy number 4: 43,773; copy number 5: 432; copy number 6: 1,709; copy number 7: 33; copy number 8: 2,742; copy number 10: 37; copy number 12: 61; copy number 14: 21; copy number 15: 1; copy number 16: 23; copy number 19: 72; copy number 22: 51; copy number 28: 2; copy number 30: 80; copy number 32: 13; copy number 41: 1; copy number 52: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-32-1970-01A-01D-0784-01): tumor purity 0.87, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 384 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:25,593,304–25,831,909, 4 genes, copy number 10: AC005165.1, AC005165.2, AC005165.3, AC018706.1.
- chr7:27,733,064–29,514,667, 21 genes, copy number 10 (within-gene range 8–10): TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1, RNU6-979P, JAZF1-AS1, PPIAP80, CREB5, AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4.
- chr7:41,960,949–57,837,046, 347 genes, copy number 12–52 (within-gene range 5–52) (broad region; genes not listed).
- chr19:38,899,700–39,032,785, 10 genes, copy number 10: NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1.
- chr19:39,726,030–39,738,029, 2 genes, copy number 10: AC006133.1, CLC.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
